Gene-level copy-number profile of tumor specimen ALCH-B1KE-TTP1-A from ALCHEMIST case ALCH-B1KE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.3 years (25,296 days).
Specimen ALCH-B1KE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c03b142b-9b94-4c0f-bd1b-ab1a2247caed.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1KE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/4fb7298e-27a0-4280-9a7d-6524b9ebc2c2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 5,284; copy number 2: 52,420; copy number 3: 615; copy number 4: 11; copy number 5: 5; copy number 10: 5; copy number 20: 5.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,266,494–89,310,144, 6 genes: IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38.
- chr2:90,309,230–91,659,972, 8 genes: AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1, LSP1P4.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr4:112,637,107–112,657,592, 7 genes: LARP7, MIR302CHG, MIR367, MIR302D, MIR302A, MIR302C, MIR302B.
- chr7:76,609,986–76,627,261, 1 gene (within-gene range 0–4): POMZP3.
- chr7:130,380,339–130,388,114, 1 gene: CPA1.
- chr8:12,676,035–12,676,389, 1 gene: AC068587.1.
- chr9:96,019,724–96,027,993, 1 gene: LINC00092.
- chr15:57,319,138–57,326,447, 2 genes: LINC01413, NDUFB10P1.
- chr16:74,456,541–74,456,611, 1 gene (within-gene range 0–2): RNU6-237P.
- chr17:2,748,078–2,748,182, 2 genes (within-gene range 0–2): MIR1253, hsa-mir-1253.
- chr17:22,298,691–22,332,410, 2 genes: FAM27E5, AC087575.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:130,459,455–130,549,883, 7 genes, copy number 5–20: POTEI, RNU6-473P, AC013269.2, Metazoa_SRP, CFC1B, AC013269.1, PRSS40B.
- chr2:241,315,100–241,354,027, 3 genes, copy number 5 (within-gene range 2–5): SEPTIN2, AC104841.1, AC005104.1.
- chr7:76,510,525–76,541,459, 5 genes, copy number 10: UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16.

Autosomal genes at a single copy (total copy number 1): 5,141. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
